Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AR, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AR-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site Code: Breast, NOS C50.9

12/21/10
JW

Final Diagnosis

Breast, left, lumpectomy: Infiltrating ductal carcinoma, Nottingham grade III (of III), [tubules 3/3, nuclei 3/3, mitoses 2/3; Nottingham score 8/9], forming a 1.8 x 1.5 x 1.5 cm mass [AJCC pT1c]. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Changes consistent with prior core biopsy site. All surgical resection margins, after re-excision of the superior margin, are negative for tumor (minimum tumor free margin, 0.5 cm, deep margin).

Lymph nodes, left axilla, axillary dissection: Multiple 5 (of 14) left axillary lymph nodes are positive for metastatic carcinoma with extranodal extension (AJCC pN2).

Just Synchronous Primary Nodules		☒

Source: NCI Genomic Data Commons file 07dadb44-7656-4bf9-ab17-01628367a82a (TCGA-AR-A1AR.747FB91B-F523-4FA0-91DD-6014EF55643D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).